Somatic mutation profile of tumor specimen TCGA-30-1855-01A (aliquot TCGA-30-1855-01A-01W-0639-09) from TCGA case TCGA-30-1855, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.3 years (22,394 days).
Specimen TCGA-30-1855-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 158cdafd-db1c-49f7-a54e-61ce6a0d75fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-30-1855-10A (Blood Derived Normal), aliquot TCGA-30-1855-10A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61d045aa-aae7-4698-ae07-7cec890da871

The open-access MAF lists 133 somatic variants for this specimen: 98 protein-altering or splice-affecting, 33 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 33, Splice Site 6, Frame Shift Del 3, Nonsense Mutation 3, Frame Shift Ins 2, In Frame Del 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.560-1G>A p.X187_splice | Splice Site (SNP) | VAF 26/35 reads (74%) | hotspot (GDC flag); catalogued as rs1202793339, CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TTN | c.46726G>T p.E15576* (on ENST00000591111; = p.E8152* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 70/270 reads (26%) | catalogued as rs1060500503, COSV60403001; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC244197.3 | c.478C>G p.P160A | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as COSV61711586, COSV61711850; called by muse, mutect2, varscan2
- AIM2 | c.389A>G p.H130R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV63702442; called by muse, mutect2, varscan2
- APBB1 | c.1252dup p.E418Gfs*12 | Frame Shift Ins (INS) | VAF 4/39 reads (10%) | catalogued as rs1378386109; called by pindel, varscan2
- CCDC149 | c.835T>A p.S279T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.247); catalogued as COSV60882701; called by muse, mutect2, varscan2
- CD163 | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100776194; called by muse, mutect2
- CDH18 | c.2270C>T p.T757M | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.901); catalogued as rs201996992, COSV56923057; called by muse, mutect2, varscan2
- CLCN6 | c.1526+1G>C p.X509_splice | Splice Site (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100412267, COSV56739682; called by muse, mutect2
- CLNK | c.561A>T p.L187F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57023690; called by muse, mutect2, varscan2
- COL22A1 | c.4432A>T p.T1478S | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV57364859; called by muse, mutect2
- CPA6 | c.598T>A p.W200R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52744772; called by muse, mutect2, varscan2
- CSHL1 | c.213G>C p.Q71H | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV99368028, COSV99368315; called by muse, mutect2
- CUL9 | c.3229T>G p.C1077G | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as rs1252681710, COSV52736044; called by muse, mutect2, varscan2
- DDX19A | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs1451860677, COSV100156250; called by muse, mutect2
- DENND4A | c.964T>C p.F322L | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101475463; called by muse, mutect2
- DENND5A | c.2599G>C p.D867H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60238569; called by muse, mutect2, varscan2
- DIAPH1 | c.1281-1G>C p.X427_splice | Splice Site (SNP) | VAF 26/72 reads (36%) | catalogued as COSV53889640; called by muse, mutect2, varscan2
- DNM2 | c.2210G>C p.G737A (on ENST00000355667 / NM_001005360.3; = p.G733A on NM_004945.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.344); catalogued as COSV99284308; called by muse, mutect2
- DOCK4 | c.982A>G p.N328D | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV70327174; called by muse, mutect2, varscan2
- DSC3 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374343226; called by muse, mutect2
- DYNC1I1 | c.1864G>T p.A622S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV61473026; called by muse, mutect2, varscan2
- EIF4G1 | c.806C>T p.S269F (on ENST00000346169 / NM_198241.3; = p.S73F on NM_004953.5) | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as rs1347558319, COSV100072410, COSV59991677; called by muse, mutect2
- EIF6 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV55772858, COSV55773780; called by muse, varscan2
- ELAC1 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs776088986, COSV53997078; called by muse, mutect2, varscan2
- FAM135B | c.2860C>A p.Q954K | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV52758245; called by muse, mutect2, varscan2
- FGF4 | c.610C>A p.P204T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51450611, COSV51451001; called by muse, mutect2, varscan2
- FYCO1 | c.3332A>G p.Q1111R | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV56120583; called by muse, mutect2, varscan2
- GJA10 | c.234G>C p.W78C | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101005446, COSV65356549; called by muse, mutect2, varscan2
- GLB1L | c.552G>C p.E184D | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55479523; called by muse, mutect2, varscan2
- GRIA2 | c.1441T>G p.W481G | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52409675; called by muse, mutect2, varscan2
- GRIN2B | c.1094T>G p.I365S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV74208343; called by muse, mutect2, varscan2
- HEATR1 | c.4968A>T p.K1656N | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.051); catalogued as COSV63983483; called by muse, mutect2, varscan2
- IL21R | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61969793, COSV61972563, COSV61973030; called by muse, mutect2, varscan2
- INPP5F | c.705C>G p.I235M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV62824368; called by muse, mutect2, varscan2
- KIR3DL1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 161/311 reads (52%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs375468097; called by muse, mutect2, varscan2
- KRT3 | c.1311G>C p.K437N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV58817657; called by muse, mutect2, varscan2
- LMOD3 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101342000, COSV70456935; called by muse, mutect2, varscan2
- LPAR1 | c.944A>G p.D315G | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62692235; called by muse, mutect2, varscan2
- LRP2 | c.7801T>C p.Y2601H | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.877); catalogued as rs554748412, COSV55578711; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC8A | c.737A>C p.K246T | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV52189848, COSV52190062; called by muse, mutect2, varscan2
- LRRIQ1 | c.5029A>G p.S1677G | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV67840225; called by muse, mutect2, varscan2
- MACF1 | c.1309C>G p.Q437E | Missense Mutation (SNP) | VAF 18/166 reads (11%) | catalogued as COSV58407901; called by muse, mutect2, varscan2
- MEP1B | c.1893G>T p.Q631H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as rs1320300430, COSV52499209, COSV52500546; called by muse, mutect2, varscan2
- METAP2 | c.1423G>C p.G475R | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51567851; called by muse, mutect2, varscan2
- NAV2 | c.2866G>A p.G956S (on ENST00000396087 / NM_001244963.2; = p.G933S on NM_145117.5) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs777242370, COSV60658618, COSV60666566; called by muse, mutect2, varscan2
- NCKAP5 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV58480051; called by muse, mutect2, varscan2
- NEDD4 | c.275A>C p.Q92P | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.688); catalogued as COSV59067505; called by muse, mutect2, varscan2
- NLGN4X | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1051301935, COSV99321667; called by muse, mutect2
- OR1S2 | c.890T>G p.M297R | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV56921109; called by muse, mutect2, varscan2
- OR4C11 | c.430G>T p.V144F | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.529); catalogued as rs141497167; called by muse, mutect2, varscan2
- OR4K1 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV53463202; called by muse, mutect2, varscan2
- PCDH15 | c.5174A>G p.E1725G | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious, low confidence (0.01); catalogued as COSV100905957; called by muse, mutect2
- PCDHB4 | c.1384_1397del p.N462Pfs*208 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as COSV52027814; called by mutect2, pindel, varscan2
- PFKFB1 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | PolyPhen benign (0); catalogued as COSV51509022; called by muse, mutect2, varscan2
- PGBD2 | c.1469T>C p.V490A | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV61401410; called by muse, mutect2, varscan2
- PSG2 | c.840G>C p.Q280H | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV100283757; called by muse, mutect2
- PTPN22 | c.2005G>C p.V669L (on ENST00000359785 / NM_001193431.2; = p.V614L on NM_012411.5) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV100704050; called by muse, mutect2
- SALL1 | c.749T>C p.I250T | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99192534; called by muse, mutect2
- SH3TC2 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV100102514; called by muse, mutect2
- SIM2 | c.592A>T p.M198L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV51773635; called by muse, mutect2, varscan2
- SLC35G3 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as rs779450428, COSV52013048; called by muse, mutect2, varscan2
- SLC4A10 | c.1055T>G p.L352W (on ENST00000446997 / NM_001354461.2; = p.L322W on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55781426, COSV99766401; called by muse, mutect2
- SLC4A10 | c.1340A>T p.Q447L (on ENST00000446997 / NM_001354461.2; = p.Q417L on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV55803672; called by muse, mutect2, varscan2
- SPIDR | c.188C>A p.P63Q | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as rs1025514898; called by muse, mutect2, varscan2
- SRGAP2 | c.1600G>A p.V534M (on ENST00000624873 / NM_001170637.4; = p.V535M on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55340545; called by muse, mutect2, varscan2
- SYNE2 | c.15887T>G p.F5296C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.593); catalogued as COSV59973638; called by muse, mutect2, varscan2
- TCF21 | c.333dup p.D112Rfs*26 | Frame Shift Ins (INS) | VAF 4/25 reads (16%) | catalogued as rs781035127; called by pindel, varscan2
- TESK2 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV59158251; called by muse, mutect2, varscan2
- TIMELESS | c.890T>G p.F297C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.808); catalogued as COSV57515986; called by muse, mutect2, varscan2
- TLL1 | c.1039C>G p.P347A | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV50262811, COSV50336137; called by muse, mutect2, varscan2
- TMEM69 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV63434311; called by muse, mutect2, varscan2
- TNNI3K | c.2394G>T p.M798I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV58548163, COSV58568262; called by muse, mutect2, varscan2
- TRHDE | c.811C>T p.H271Y | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.877); catalogued as COSV53869909; called by muse, mutect2, varscan2
- TRIM33 | c.2464C>G p.L822V | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs763011367, COSV61826499; called by muse, mutect2, varscan2
- TRPC4 | c.1942G>T p.E648* | Nonsense Mutation (SNP) | VAF 9/82 reads (11%) | catalogued as COSV59022499; called by muse, mutect2, varscan2
- TRPM7 | c.406G>C p.V136L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.77); PolyPhen benign (0.015); catalogued as COSV57922633; called by muse, mutect2, varscan2
- TSHZ1 | c.2561A>G p.K854R (on ENST00000580243 / NM_001308210.2; = p.K809R on NM_005786.6) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59018661; called by muse, mutect2, varscan2
- TSHZ2 | c.2957C>A p.A986D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100296921; called by muse, mutect2
- TTN | c.22480G>T p.A7494S (on ENST00000591111; = p.A6567S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | PolyPhen benign (0.033); catalogued as COSV100635123; called by muse, mutect2
- TTN | c.18197A>G p.E6066G (on ENST00000591111; = p.E5139G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | PolyPhen probably damaging (0.997); catalogued as COSV60403043; called by muse, mutect2, varscan2
- TUBA1B | c.226+1G>T p.X76_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as COSV60138645; called by muse, mutect2, varscan2
- TUBB1 | c.1149G>T p.E383D | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV53888673; called by muse, mutect2, varscan2
- UEVLD | c.911G>A p.W304* | Nonsense Mutation (SNP) | VAF 3/39 reads (8%) | catalogued as COSV100293460; called by muse, mutect2
- UNC5D | c.1919A>G p.Q640R | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.341); catalogued as COSV54843025; called by muse, mutect2, varscan2
- ZFHX4 | c.6437C>A p.A2146D | Missense Mutation (SNP) | VAF 55/65 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV51500955; called by muse, mutect2, varscan2
- ZNF493 | c.1903C>G p.H635D | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV62753024; called by muse, mutect2, varscan2
- ZNF536 | c.1909G>A p.G637S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1392485761, COSV62820033; called by muse, mutect2, varscan2
- ZNF625 | c.920A>C p.Q307P | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as COSV63243478; called by muse, mutect2, varscan2
- ZNF668 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.714); catalogued as COSV100337006; called by muse, mutect2
- BCL9L | c.2020del p.V674Sfs*38 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | called by mutect2, pindel, varscan2
- CAPN9 | c.1574del p.A525Vfs*13 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by pindel*, varscan2
- CHD2 | c.3605C>G p.P1202R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.694); called by muse, mutect2
- DNAH9 | c.9468_9479del p.L3157_A3160del | In Frame Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- GRHL2 | c.1459_1485+11del p.X487_splice | Splice Site (DEL) | VAF 16/178 reads (9%) | called by mutect2, pindel
- NFKBIA | c.622_633del p.D208_A211del | In Frame Del (DEL) | VAF 7/17 reads (41%) | called by mutect2, varscan2
- SLC4A5 | c.1268+1_1268+17del p.X423_splice | Splice Site (DEL) | VAF 12/60 reads (20%) | called by mutect2, pindel
- USP28 | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, mutect2
- AKT1 | c.366G>A p.S122= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs777639707, COSV62576651; called by mutect2, varscan2
- APC | c.2784C>G p.A928= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV57388958; called by muse, mutect2
- ATP8A1 | c.1239T>G p.T413= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV52550492; called by muse, mutect2, varscan2
- CLIP1 | c.2427T>C p.I809= (on ENST00000620786 / NM_001247997.1; = p.I798= on NM_002956.2) | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV56799313, COSV56809742; called by muse, mutect2, varscan2
- CRACD | c.3597G>A p.R1199= | Silent (SNP) | VAF 32/177 reads (18%) | catalogued as COSV51733717; called by muse, mutect2, varscan2
- DENND3 | c.2361G>A p.A787= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs570647400, COSV52807824; called by muse, mutect2, varscan2
- DST | c.11910A>C p.S3970= (on ENST00000361203 / NM_001374722.1; = p.S1558= on NM_015548.5) | Silent (SNP) | VAF 16/178 reads (9%) | catalogued as COSV55005965, COSV99761026; called by muse, mutect2
- EDN3 | c.381T>C p.Y127= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs1362741019, COSV61110696; called by muse, mutect2, varscan2
- FLG | c.11745T>C p.S3915= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV64251567; called by muse, mutect2, varscan2
- GDAP2 | c.615T>C p.F205= | Silent (SNP) | VAF 36/130 reads (28%) | catalogued as COSV65613556; called by muse, mutect2, varscan2
- GPR39 | c.1011G>A p.S337= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs1558870597, COSV61415842; called by muse, mutect2, varscan2
- IGLV4-3 | c.291C>T p.T97= | Silent (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- KRT2 | c.522G>A p.V174= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs747629711, COSV59013085; called by muse, mutect2, varscan2
- MBD1 | c.309G>A p.Q103= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV54008080; called by muse, mutect2, varscan2
- NUP160 | c.3346C>A p.R1116= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as COSV65856495; called by muse, mutect2, varscan2
- OR2T2 | c.753T>G p.V251= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV61619333; called by muse, varscan2
- PCDHB13 | c.1878C>T p.T626= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs1231448576, COSV53401846; called by muse, varscan2
- PDZRN4 | c.1641C>T p.N547= (on ENST00000402685 / NM_001164595.2; = p.N289= on NM_013377.4) | Silent (SNP) | VAF 6/79 reads (8%) | catalogued as COSV100115794; called by muse, mutect2
- PIK3R1 | c.2151A>C p.P717= (on ENST00000521381 / NM_181523.3; = p.P447= on NM_181504.4) | Silent (SNP) | VAF 72/99 reads (73%) | catalogued as COSV57141881; called by muse, mutect2, varscan2
- PON3 | c.1047T>C p.T349= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV55702459; called by muse, mutect2, varscan2
- PRAMEF4 | c.1257G>T p.R419= | Silent (SNP) | VAF 84/270 reads (31%) | catalogued as COSV99340351; called by mutect2, varscan2
- SLC25A51 | c.519T>C p.Y173= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV54253912; called by muse, mutect2, varscan2
- SLC28A1 | c.394C>T p.L132= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs1420760773, COSV54487309; called by muse, mutect2, varscan2
- SLC36A2 | c.558C>T p.N186= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs1237573530, COSV58865522; called by muse, mutect2, varscan2
- SND1 | c.969G>A p.L323= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV61250675; called by muse, mutect2, varscan2
- SPATA31D1 | c.427C>T p.L143= | Silent (SNP) | VAF 64/114 reads (56%) | catalogued as COSV61202286; called by muse, mutect2, varscan2
- TARBP1 | c.1914G>A p.L638= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs1446689169, COSV50212524; called by muse, mutect2
- TCF12 | c.1341C>A p.L447= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV51031039; called by muse, mutect2, varscan2
- TMTC4 | c.1971G>C p.S657= (on ENST00000376234 / NM_001350577.2; = p.S676= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs571739383, COSV60893868; called by muse, mutect2, varscan2
- TULP4 | c.1044C>A p.I348= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs771695589, COSV65581896; called by muse, mutect2, varscan2
- TUT4 | c.453A>G p.E151= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs745702306, COSV57120603; called by muse, mutect2, varscan2
- WASHC2A | c.3978G>A p.K1326= | Silent (SNP) | VAF 42/158 reads (27%) | catalogued as rs749645672, COSV50956390; called by muse, mutect2, varscan2
- WDR89 | c.1036T>C p.L346= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs1040212891, COSV50828116; called by muse, mutect2, varscan2
- SH2D6 | n.362G>A | RNA (SNP) | VAF 3/8 reads (38%) | catalogued as rs745438002, COSV61064371; called by muse, mutect2, varscan2
- SLIRP | c.*316C>A | 3'UTR (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99834569; called by muse, mutect2
